Somatic mutation profile of tumor specimen TCGA-P6-A5OF-01A (aliquot TCGA-P6-A5OF-01A-11D-A29I-10) from TCGA case TCGA-P6-A5OF, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 55.0 years (20,106 days).
Specimen TCGA-P6-A5OF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 691c70bd-4bec-47ad-9438-2a3207bc443c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P6-A5OF-10A (Blood Derived Normal), aliquot TCGA-P6-A5OF-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3238c55f-2b73-4db4-83cc-ae4136d71d5f

The open-access MAF lists 26 somatic variants for this specimen: 16 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 11, Silent 10, Nonsense Mutation 2, In Frame Del 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNEP1R1 | c.140G>T p.W47L (on ENST00000427478 / NM_001281789.1; = p.W64L on NM_153261.5) | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.437); catalogued as COSV101208082; called by muse, mutect2, varscan2
- COL18A1 | c.5081C>T p.S1694L (on ENST00000359759 / NM_130444.3; = p.S1459L on NM_030582.4) | Missense Mutation (SNP) | VAF 46/546 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750175097; called by muse, mutect2
- MEN1 | c.809G>A p.W270* | Nonsense Mutation (SNP) | VAF 13/21 reads (62%) | catalogued as CM970930, COSV53647840; called by muse, mutect2, varscan2
- TCEAL6 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs376334850, COSV65653903; called by muse, mutect2, varscan2
- ASXL3 | c.4748C>T p.A1583V | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CD63 | c.696A>C p.R232S | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- CHD7 | c.7478C>G p.P2493R | Missense Mutation (SNP) | VAF 118/210 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- GPR141 | c.436A>T p.I146F | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MGA | c.6563del p.G2188Efs*14 (on ENST00000219905 / NM_001164273.1; = p.G1979Efs*14 on NM_001080541.2) | Frame Shift Del (DEL) | VAF 27/46 reads (59%) | called by mutect2, pindel, varscan2
- PCDHAC1 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- POLR1F | c.58_78del p.V20_L26del | In Frame Del (DEL) | VAF 25/86 reads (29%) | called by mutect2, pindel*, varscan2*
- PPP5C | c.286A>T p.I96F | Missense Mutation (SNP) | VAF 108/232 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SAMD5 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SLC24A2 | c.410T>C p.L137P | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNRF3 | c.1015G>T p.E339* (on ENST00000544604 / NM_001206998.2; = p.E239* on NM_032173.3) | Nonsense Mutation (SNP) | VAF 86/105 reads (82%) | called by muse, mutect2, varscan2
- ZNRF3 | c.1015+1G>T p.X339_splice (on ENST00000544604 / NM_001206998.2; = p.X239_splice on NM_032173.3) | Splice Site (SNP) | VAF 84/103 reads (82%) | called by muse, mutect2, varscan2
- BHLHE41 | c.585C>T p.A195= | Silent (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2
- CLPP | c.426G>A p.P142= | Silent (SNP) | VAF 12/182 reads (7%) | catalogued as rs771153538; called by muse, mutect2
- HYLS1 | c.768G>A p.Q256= | Silent (SNP) | VAF 5/102 reads (5%) | called by muse, mutect2
- IRS4 | c.417C>A p.P139= | Silent (SNP) | VAF 15/45 reads (33%) | called by muse, mutect2, varscan2
- KRT85 | c.766C>T p.L256= | Silent (SNP) | VAF 24/143 reads (17%) | called by muse, mutect2, varscan2
- MCOLN1 | c.96T>A p.P32= | Silent (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2, varscan2
- TDP1 | c.921T>C p.D307= | Silent (SNP) | VAF 23/41 reads (56%) | catalogued as rs761149291; called by muse, mutect2, varscan2
- TSNARE1 | c.141G>T p.S47= | Silent (SNP) | VAF 53/135 reads (39%) | called by muse, mutect2, varscan2
- USP31 | c.642G>A p.V214= | Silent (SNP) | VAF 48/108 reads (44%) | called by muse, varscan2
- ZNF208 | c.63G>A p.L21= | Silent (SNP) | VAF 20/154 reads (13%) | called by muse, mutect2, varscan2
